Somatic mutation profile of tumor specimen TCGA-AR-A24O-01A (aliquot TCGA-AR-A24O-01A-11D-A167-09) from TCGA case TCGA-AR-A24O, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 43.7 years (15,977 days).
Specimen TCGA-AR-A24O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88e6a722-f7d1-4d85-a1de-0428609994f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A24O-10A (Blood Derived Normal), aliquot TCGA-AR-A24O-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/936967be-efbd-4315-a796-148b8a32f00e

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51644739; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.3407G>A p.S1136N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1423321006, COSV101329986; called by muse, mutect2
- BRWD1 | c.3007G>T p.E1003* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as COSV60903539; called by muse, mutect2, varscan2
- CHD6 | c.4008-1G>C p.X1336_splice | Splice Site (SNP) | VAF 21/85 reads (25%) | catalogued as COSV58561654, COSV58563027; called by muse, mutect2, varscan2
- CPXM2 | c.1987G>A p.V663I | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); catalogued as rs138679076; called by muse, mutect2, varscan2
- EFNB2 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as COSV55367761, COSV99809013; called by muse, mutect2, varscan2
- H1-3 | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99768685; called by muse, mutect2, varscan2
- NHS | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as CD094131, COSV66270875, COSV66274383; called by muse, mutect2, varscan2
- PALLD | c.1981G>T p.A661S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs878854267, COSV99824305; called by muse, mutect2
- PCYT1A | c.626T>G p.I209S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53060747; called by muse, mutect2, varscan2
- SENP1 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs1220214600, COSV50308650; called by muse, mutect2, varscan2
- SLC30A10 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745609179, COSV63072002; called by muse, mutect2, varscan2
- TUBGCP3 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs758583156, COSV56191437; called by muse, mutect2, varscan2
- VPS53 | c.1405C>A p.P469T (on ENST00000571805 / NM_001366253.2; = p.P440T on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as COSV99345682; called by muse, mutect2
- ZNF75A | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV73039726; called by muse, mutect2, varscan2
- GPS2 | c.141_148del p.Q48Kfs*46 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.5491C>T p.L1831= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99734836; called by muse, mutect2
- DOCK10 | c.4755C>G p.A1585= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV51430117; called by muse, mutect2, varscan2
- KBTBD12 | c.132C>T p.C44= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100675391; called by muse, mutect2, varscan2
- PKHD1L1 | c.4311T>C p.Y1437= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV65755143; called by muse, mutect2, varscan2
